Surgical pathology report (de-identified scan), TCGA case TCGA-CM-5863, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-5863-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT

Clinical Diagnosis & History:
Colon carcinoma (hepatic flexure).

Specimens Submitted:
1: SP: Terminal ileum, cecum, ascending colon; right hemicolectomy

DIAGNOSIS:
1. SP: Terminal ileum, cecum, ascending colon; right hemicolectomy:

Tumor Type:
Mucinous adenocarcinoma

Histologic Grade:
Moderately differentiated

Tumor Location:
Ascending colon

Tumor Size:
Length is 6 cm
Width is 10 cm
Maximal thickness is 1 cm

Tumor Budding:
Absent

Increased Tumor Infiltrating Lymphocytes:
Absent

Precursor Lesions:
Not identified

Deepest Tumor Invasion:
Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:
Not identified

Lymphovascular Invasion:
Suspected

Large Venous Invasion:
Not Identified

Perineural Invasion:
Identified

Surgical Margins:
Free of tumor

Polyps/Mucosa Dysplasia (away from the carcinoma):
Not Identified

Non-Neoplastic Bowel:
Unremarkable

** Continued on next page **

[page 2 of 3]
Appendix:

Not identified

Lymph Nodes:

Number with metastasis: 3

Total number examined: 12

Tumor deposits in pericorectal soft tissue:

Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N1b (Metastasis in 2-3 regional lymph nodes)

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

1). The specimen is received fresh, labeled "Right colon" and consists of a segment of terminal ileum, cecum, and ascending colon. The terminal ileum measures 5.5 cm in length and 4.5 cm in circumference at the proximal resected margin. The remaining colon measures 17 in length with a circumference of 5.4 cm at the distal resected margin. There is no attached appendix identified. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 1.1 cm in thickness. The specimen is opened to reveal a friable polypoid mass lesion measuring 6.0 cm in length and 10.0 cm in width. The mass is located in the ascending colon, 10.3 cm from the proximal margin and 5.0 cm from the distal margin. Sectioning shows the tumor invades the muscularis and abuts the underlying adipose tissue. The depth of invasion is 1.0 cm grossly. There is a 1.5 x 0.6 x 0.5 cm gelatinous filled cyst cavity identified in the tumor. The remaining mucosa is tan-brown with the normal folds. The ileocecal valve is grossly edematous. The attached adipose tissue is submitted for lymph node dissections. Representative sections of the specimen are submitted for permanent sections and for

Summary of sections:

P - proximal margin shave

D - distal margin shave

T - tumor

C--cyst

IC--ileocecal valve

RS -representative sections

** Continued on next page **

[page 3 of 3]
----- Page 3 of 3
LN - lymph nodes
BLN - bisected lymph nodes

Summary of Sections:

Part 1: SP: Terminal ileum, cecum, ascending colon; right hemicolectomy

Block	Sect.	Site	PCs
1		C	1
2		DM	4
1		IC	2
6		LN	15
1		PM	2
1		RS	2
8		T	8

** End of Report **

Source: NCI Genomic Data Commons file 0f54867b-c506-41cc-a7d1-c2787d7ec947 (TCGA-CM-5863.1441EA9A-3FE4-4EE3-B22D-D73BB53EA399.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).